Gene-level copy-number profile of tumor specimen TCGA-22-5478-01A from TCGA case TCGA-22-5478, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 79.3 years (28,978 days).
Specimen TCGA-22-5478-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.7dcace17-98bd-4c98-9eb3-1bd897bd6cf8.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-22-5478-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/b92f3757-3422-4a80-8759-76afd9e85860

Most common (modal) total copy number across autosomal genes: 1 — below the diploid value of 2.
Genes by total copy number (all chromosomes): copy number 1: 25,344; copy number 2: 22,168; copy number 3: 9,223; copy number 4: 1,836; copy number 5: 637; copy number 6: 269; copy number 7: 221; copy number 8: 27; copy number 9: 90.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-22-5478-01A-01D-1631-01): tumor purity 0.4, ploidy 3.75, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 3, i.e. more than twice the modal value of 1; autosomes only): 12,303 genes in 31 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:38,814–51,225,575, 842 genes, copy number 3 (within-gene range 2–3) (broad region; genes not listed).
- chr2:51,925,692–97,703,064, 931 genes, copy number 3 (broad region; genes not listed).
- chr4:49,096–58,118,070, 874 genes, copy number 3–9 (broad region; genes not listed).
- chr5:58,198–45,895,970, 710 genes, copy number 4–5 (broad region; genes not listed).
- chr7:70,972–159,233,377, 3,014 genes, copy number 3–6 (broad region; genes not listed).
- chr8:37,326,575–38,144,076, 32 genes, copy number 6: AC091182.1, AC091182.2, LINC01605, AC124067.1, AC124067.2, AC124067.3, AC124067.4, AC137579.2, AC137579.1, RNU6-607P, ZNF703, AC138356.3, AC138356.1, ERLIN2, AC138356.2, PLPBP, ADGRA2, BRF2, RAB11FIP1, AC130304.1, RN7SL709P, GOT1L1, AC144573.1, ADRB3, RPL12P48, EIF4EBP1, AP006545.1, AP006545.3, AP006545.2, ASH2L, RNU6-988P, AC084024.1.
- chr8:43,246,755–145,066,685, 1,555 genes, copy number 3 (broad region; genes not listed).
- chr17:13,494,032–27,894,752, 451 genes, copy number 3 (broad region; genes not listed).
- chr17:60,677,453–61,392,838, 1 gene, copy number 3 (within-gene range 1–3): BCAS3.
- chr17:60,899,891–83,095,122, 720 genes, copy number 3 (broad region; genes not listed).
- chr18:20,946,906–48,479,228, 379 genes, copy number 3–9 (broad region; genes not listed).
- chr18:48,564,795–48,662,635, 2 genes, copy number 9: AC048380.2, AC048380.3.
- chr18:61,905,255–80,247,514, 261 genes, copy number 3 (broad region; genes not listed).
- chr19:18,442,663–20,661,596, 114 genes, copy number 3–4 (within-gene range 2–4) (broad region; genes not listed).
- chr19:53,365,693–58,315,183, 391 genes, copy number 3–4 (within-gene range 2–4) (broad region; genes not listed).
- chr20:87,250–675,802, 22 genes, copy number 4–7: DEFB125, DEFB126, DEFB127, DEFB128, DEFB129, DEFB132, AL034548.1, C20orf96, ZCCHC3, AL034548.2, NRSN2-AS1, SOX12, NRSN2, TRIB3, RBCK1, TBC1D20, Y_RNA, CSNK2A1, TCF15, SRXN1, AL121758.1, SCRT2.
- chr20:1,442,162–4,075,165, 95 genes, copy number 4–9 (broad region; genes not listed).
- chr20:7,882,985–8,968,360, 7 genes, copy number 5–8 (within-gene range 1–8): HAO1, TMX4, AL021396.1, PLCB1, PHKBP1, PLCB1-IT1, RNU105B.
- chr20:9,068,763–13,996,443, 63 genes, copy number 4–8 (broad region; genes not listed).
- chr20:14,003,508–14,352,425, 5 genes, copy number 4: RPS3P1, AIMP1P1, RN7SL864P, FLRT3, RNU6-228P.
- chr20:15,619,494–16,864,148, 14 genes, copy number 4: ENSAP1, AL079338.1, AL161941.1, PPIAP17, KIF16B, AL049794.1, AL049794.2, RPLP0P1, Y_RNA, AL135938.1, AL034428.1, SNRPB2, OTOR, AL121892.1.
- chr20:18,258,554–20,370,949, 48 genes, copy number 4: RN7SL14P, RNU2-56P, AL049646.2, ZNF133, AL049646.1, RN7SKP74, ZNF133-AS1, LINC00851, DZANK1, GCNT1P1, RNA5SP476, POLR3F, MIR3192, RPL21P3, RBBP9, RPS19P1, SEC23B, SMIM26, AL121900.1, DTD1, RN7SL638P, RNU6ATAC34P, DUXAP7, DTD1-AS1, EEF1A1P34, LINC00652, LINC00653, SCP2D1-AS1, SCP2D1, AL135936.1, AL136090.2, SLC24A3, AL136090.1, SLC24A3-AS1, AL121830.1, AL121761.1, RIN2, RPL12P12, NAA20, CRNKL1, CFAP61, AL035454.1, AL049648.1, RPL17P1, CFAP61-AS1, RN7SL690P, AL161658.1, INSM1.
- chr20:23,125,068–32,743,567, 197 genes, copy number 4–6 (broad region; genes not listed).
- chr20:32,858,923–33,650,036, 20 genes, copy number 5 (within-gene range 1–5): EFCAB8, SUN5, BPIFB2, BPIFB6, PUDPP3, BPIFB3, BPIFB4, BPIFA2, SOCS2P1, BPIFA4P, AL121901.1, BPIFA3, BPIFA1, RPL12P3, BPIFB1, BPIFB5P, BPIFB9P, CDK5RAP1, SNTA1, CBFA2T2.
- chr20:34,194,569–38,033,461, 125 genes, copy number 4–5 (within-gene range 1–5) (broad region; genes not listed).
- chr20:38,304,150–39,815,097, 39 genes, copy number 4 (within-gene range 1–4): BPI, LBP, AL391095.2, AL391095.1, AL391095.3, SNHG17, SNORA71, SNORA71B, SNORA71A, SNORA71C, SNORA71D, SNORA71, SNHG11, SNORA71E, SNORA60, RALGAPB, MIR548O2, RPS3P2, ADIG, ARHGAP40, AL035419.1, Metazoa_SRP, SLC32A1, ACTR5, RN7SKP173, PPP1R16B, RN7SL116P, FAM83D, AL023803.2, AL023803.1, DHX35, AL023803.3, NPM1P19, LINC01734, AL035251.1, ATG3P1, RN7SL680P, AL132981.1, AL118523.1.
- chr20:40,685,848–41,712,600, 23 genes, copy number 4–7: MAFB, AL035665.1, AL035665.2, RNA5SP484, RNU2-52P, TOP1, PLCG1-AS1, PLCG1, MIR6871, ZHX3, AL022394.1, RPL23AP81, RN7SL615P, ADI1P1, LPIN3, EMILIN3, AL031667.1, CHD6, AL031667.2, AL031667.3, RPL12P11, RNU6-1018P, AL133229.1.
- chr20:43,914,852–54,651,169, 276 genes, copy number 4–8 (broad region; genes not listed).
- chr20:63,502,287–64,313,132, 56 genes, copy number 4: AL121829.1, PPDPF, PTK6, SRMS, AL121829.2, FNDC11, HELZ2, GMEB2, MHENCR, STMN3, RTEL1, RTEL1-TNFRSF6B, TNFRSF6B, ARFRP1, ZGPAT, AL121845.3, AL121845.4, LIME1, AL121845.2, SLC2A4RG, ZBTB46, AL121845.1, ZBTB46-AS1, C20orf181, AL118506.1, ABHD16B, TPD52L2, DNAJC5, RNU1-134P, MIR941-1, MIR941-2, MIR941-3, MIR941-4, MIR941-5, UCKL1, MIR1914, MIR647, UCKL1-AS1, ZNF512B, SAMD10, PRPF6, C20orf204, SOX18, TCEA2, AL355803.1, RGS19, MIR6813, OPRL1, LKAAEAR1, AL121581.3, MYT1, NPBWR2, PCMTD2, AL137028.2, CICP4, LINC00266-1.
- chr22:15,290,718–37,427,479, 941 genes, copy number 3 (broad region; genes not listed).
- chr22:48,044,710–50,801,309, 95 genes, copy number 3 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 23,064. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
